Somatic mutation profile of tumor specimen TCGA-CN-6020-01A (aliquot TCGA-CN-6020-01A-11D-1683-08) from TCGA case TCGA-CN-6020, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 58.1 years (21,232 days).
Specimen TCGA-CN-6020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6abe2fc1-476e-4dbf-9a24-64a7eff1fffd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6020-10A (Blood Derived Normal), aliquot TCGA-CN-6020-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/548373e1-db07-4e5d-94f3-b1c28ba9b27f

The open-access MAF lists 144 somatic variants for this specimen: 106 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 35, Nonsense Mutation 8, Frame Shift Del 3, Splice Region 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.1841G>A p.G614E | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV100228495; called by muse, mutect2, varscan2
- AARS2 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.412); catalogued as COSV99771197; called by muse, mutect2
- ACOT12 | c.258G>T p.E86D | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296708; called by muse, mutect2, varscan2
- ADAM7 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV99442935; called by muse, mutect2, varscan2
- AGT | c.1261G>C p.V421L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV100794196; called by muse, mutect2, varscan2
- AMZ1 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.956); catalogued as COSV100406161, COSV56688952; called by muse, mutect2
- ANKMY1 | c.1114A>G p.M372V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99801199; called by muse, mutect2, varscan2
- APC | c.3085C>A p.L1029I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99965023; called by muse, mutect2
- ASB5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.163); catalogued as rs371622915; called by muse, mutect2, varscan2
- ATP13A4 | c.2081G>A p.R694Q | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.274); catalogued as rs144335118, COSV61319555; called by muse, mutect2, varscan2
- ATP9B | c.493A>T p.I165L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100302818; called by muse, mutect2, varscan2
- BTBD1 | c.656T>A p.I219N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99915189; called by muse, mutect2
- CABLES1 | c.1781G>A p.R594Q (on ENST00000256925 / NM_001100619.2; = p.R329Q on NM_138375.2) | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs186772636, COSV99908259; called by muse, mutect2
- CACNB3 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs146819236; called by muse, mutect2, varscan2
- CATSPERG | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs560292125, COSV99286032; called by muse, mutect2, varscan2
- CCDC158 | c.2178G>T p.M726I | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV101187144, COSV66356005; called by muse, mutect2, varscan2
- CFAP58 | c.1887G>C p.E629D | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100866027; called by muse, mutect2, varscan2
- CGNL1 | c.1758G>C p.Q586H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV55570165, COSV99847416; called by muse, mutect2, varscan2
- CLK3 | c.1425C>A p.D475E (on ENST00000395066 / NM_001130028.1; = p.D327E on NM_003992.4) | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV100165755; called by muse, mutect2, varscan2
- CPSF1 | c.2707G>T p.E903* | Nonsense Mutation (SNP) | VAF 39/150 reads (26%) | catalogued as COSV100450160; called by muse, varscan2
- CYP2C8 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs765827545, COSV100987876; called by muse, mutect2, varscan2
- CYTIP | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV51633316; called by muse, mutect2, varscan2
- DDX43 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as COSV100946214; called by muse, mutect2, varscan2
- DLG2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV54674113; called by muse, mutect2, varscan2
- DMKN | c.422C>T p.A141V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100303161; called by muse, mutect2, varscan2
- DNAH17 | c.13166G>C p.G4389A | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99427984; called by muse, mutect2, varscan2
- DNAH5 | c.2551T>A p.C851S | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99444614; called by muse, mutect2
- DOCK11 | c.4249C>T p.Q1417* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99352801; called by muse, mutect2
- ELAVL2 | c.238T>A p.L80M | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV99805323; called by muse, mutect2
- EPHA6 | c.659A>G p.N220S | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1239242656, COSV101060778; called by muse, mutect2
- FAM111A | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV100659321; called by muse, mutect2, varscan2
- FAM47A | c.2239G>T p.G747C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649707; called by muse, mutect2, varscan2
- FAT3 | c.10927G>A p.E3643K | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99961570; called by muse, mutect2
- FGFRL1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV99294427; called by muse, mutect2
- FRMPD1 | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs774561681, COSV100899266; called by muse, mutect2, varscan2
- GCC2 | c.4924A>G p.I1642V | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100565238; called by muse, mutect2
- GLG1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as COSV99215240; called by muse, mutect2, varscan2
- GNB1L | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV100283901, COSV61547846; called by muse, mutect2, varscan2
- HECW2 | c.3652T>C p.L1218= | Splice Region (SNP) | VAF 10/62 reads (16%) | catalogued as COSV99645763; called by muse, mutect2, varscan2
- HTT | c.5489C>T p.P1830L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100750370; called by muse, mutect2, varscan2
- HYPK | c.29A>T p.E10V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV99979593; called by muse, mutect2, varscan2
- IL1RAPL1 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100145000; called by muse, mutect2, varscan2
- IMPG1 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV100885941, COSV64062750; called by muse, mutect2
- KCNA3 | c.536T>A p.I179N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100871195; called by muse, mutect2, varscan2
- KCND2 | c.1602C>G p.H534Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.041); catalogued as COSV100473331; called by muse, mutect2, varscan2
- KCNJ4 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1211791138, COSV57856309; called by muse, mutect2, varscan2
- KLHL24 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV99664689; called by muse, mutect2
- LRIT2 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100928287; called by muse, mutect2
- LRRC39 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149823600; called by muse, mutect2, varscan2
- LRRK2 | c.953T>A p.L318H | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.928); catalogued as COSV100109105; called by muse, mutect2
- MAST2 | c.2863C>T p.Q955* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as rs1005543253, COSV63619444; called by muse, mutect2
- MATN2 | c.1094G>T p.C365F | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645615; called by muse, mutect2, varscan2
- MIF4GD | c.185T>A p.I62N (on ENST00000325102 / NM_001370592.1; = p.I96N on NM_020679.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99821444; called by muse, mutect2
- MKI67 | c.5419G>C p.D1807H | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100896136; called by muse, mutect2
- MLLT10 | c.2548C>T p.P850S (on ENST00000307729 / NM_001195626.3; = p.P866S on NM_004641.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as COSV100307412; called by muse, mutect2, varscan2
- MUC17 | c.9458G>A p.S3153N | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as rs1301440376, COSV100071483; called by muse, mutect2, varscan2
- NEB | c.16562C>G p.S5521C | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99414451; called by muse, mutect2, varscan2
- NUP155 | c.1521G>C p.G507= (on ENST00000231498 / NM_153485.3; = p.G448= on NM_004298.4) | Splice Region (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99192185; called by muse, mutect2
- NUP160 | c.2883G>T p.Q961H | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV101021265; called by muse, mutect2, varscan2
- OR10A3 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100660209; called by muse, mutect2, varscan2
- OR14A16 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV100713686, COSV100713897; called by muse, mutect2, varscan2
- PDZRN4 | c.2815C>T p.R939C (on ENST00000402685 / NM_001164595.2; = p.R681C on NM_013377.4) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144265671, COSV54192124; called by muse, mutect2, varscan2
- PEG3 | c.2605A>C p.N869H | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV99687107; called by muse, mutect2, varscan2
- PEX1 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as COSV50424276; called by muse, mutect2, varscan2
- PNMA8B | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as COSV66537716; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2038T>A p.S680T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.329); catalogued as COSV99460749; called by muse, mutect2, varscan2
- PRKG1 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100907126; called by muse, mutect2, varscan2
- PRSS16 | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100041709; called by muse, mutect2, varscan2
- PTPN13 | c.4637G>C p.G1546A (on ENST00000411767 / NM_080683.3; = p.G1527A on NM_006264.3) | Missense Mutation (SNP) | VAF 7/119 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363976; called by muse, mutect2
- PWWP3B | c.1217G>A p.W406* | Nonsense Mutation (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100530903; called by muse, varscan2
- RFPL3 | c.674G>A p.R225H (on ENST00000249007 / NM_001098535.1; = p.R196H on NM_006604.2) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs749020089, COSV50750672; called by muse, mutect2, varscan2
- RP1 | c.5540T>C p.I1847T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs757250217, COSV99606194; called by muse, mutect2, varscan2
- RPS6KA1 | c.1469A>T p.E490V | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100942905; called by muse, mutect2, varscan2
- RYR2 | c.5443G>A p.E1815K | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1294638169, COSV63657858; called by muse, mutect2, varscan2
- SALL4 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.235); catalogued as rs770743300, COSV53849955; called by muse, mutect2, varscan2
- SLC12A7 | c.2943G>T p.W981C | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99369276; called by muse, mutect2
- SMPDL3A | c.735G>C p.E245D | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100868661; called by muse, mutect2, varscan2
- SPOCK3 | c.1048A>T p.T350S | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.067); catalogued as COSV100691755; called by muse, mutect2, varscan2
- SUN1 | c.615del p.V208Cfs*103 (on ENST00000405266 / NM_001367651.1; = p.V158Cfs*33 on NM_025154.6 and 13 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 64/328 reads (20%) | catalogued as COSV61778584; called by pindel, varscan2
- TENT5C | c.955G>T p.V319L | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101032744, COSV65616425; called by muse, mutect2, varscan2
- THBS1 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV99527545; called by muse, mutect2
- TICRR | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV99176005; called by muse, mutect2, varscan2
- TM4SF1 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV100542934; called by muse, mutect2, varscan2
- TMEM132B | c.1538G>A p.W513* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100168429, COSV100168711; called by muse, mutect2, varscan2
- TNIK | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99454884; called by muse, mutect2, varscan2
- TP53 | c.672G>T p.E224D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs267605076, CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TROAP | c.839G>A p.G280D | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57746198; called by muse, mutect2, varscan2
- TRPM1 | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762311684, COSV56634753; called by muse, mutect2, varscan2
- TTC22 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1243352201, COSV100827460; called by muse, mutect2
- TTN | c.71867G>C p.R23956T (on ENST00000591111; = p.R16532T on NM_003319.4) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | PolyPhen possibly damaging (0.647); catalogued as COSV100593158; called by muse, mutect2
- TTN | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 21/72 reads (29%) | PolyPhen possibly damaging (0.605); catalogued as COSV100593161; called by muse, mutect2, varscan2
- UGT2B11 | c.377T>A p.F126Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV101485214; called by muse, mutect2, varscan2
- UGT2B15 | c.1343G>T p.R448I | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV57734373; called by muse, mutect2
- USF3 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.182); catalogued as COSV100324693; called by muse, mutect2, varscan2
- YY1AP1 | c.832A>G p.S278G (on ENST00000295566 / NM_139118.2; = p.S201G on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as rs201495677, COSV99803384; called by muse, mutect2, varscan2
- ZNF112 | c.2132A>C p.H711P (on ENST00000337401 / NM_001083335.2; = p.H705P on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100495462; called by muse, mutect2
- ZNF527 | c.482G>C p.R161T | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.048); catalogued as COSV62236139; called by muse, mutect2
- ZNF623 | c.905A>T p.H302L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.399); catalogued as rs1219945495, COSV101513465; called by muse, mutect2, varscan2
- ZNF75D | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as COSV66133371; called by muse, mutect2
- ZNFX1 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.306); catalogued as rs781439672, COSV100870723, COSV65573756; called by muse, mutect2
- GAS2L2 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- OR4S2 | c.605_623del p.G202Vfs*6 | Frame Shift Del (DEL) | VAF 21/129 reads (16%) | called by mutect2, pindel, varscan2
- RP1 | c.6010A>G p.R2004G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2
- SMG1 | c.9392_9393del p.K3131Sfs*4 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); called by mutect2, varscan2
- SREK1 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- AL592490.1 | c.2406C>T p.G802= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV69427601; called by muse, mutect2, varscan2
- BSN | c.3327G>A p.L1109= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV99607156; called by muse, mutect2, varscan2
- CD163 | c.210G>A p.E70= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100775618; called by muse, mutect2, varscan2
- CHRM3 | c.1734G>A p.S578= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs200918197, COSV99697404; called by muse, mutect2, varscan2
- COL14A1 | c.966G>A p.L322= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99917936; called by muse, mutect2
- DDX43 | c.78G>T p.A26= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as COSV100946211; called by muse, mutect2, varscan2
- GBP4 | c.828C>T p.F276= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV63255088; called by muse, mutect2
- GOPC | c.528A>G p.E176= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99270664; called by muse, mutect2
- HEXA | c.219C>T p.F73= | Silent (SNP) | VAF 26/202 reads (13%) | catalogued as COSV99173666; called by muse, mutect2, varscan2
- IL13 | c.111G>T p.V37= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100449374; called by muse, mutect2, varscan2
- KIF14 | c.3288A>G p.E1096= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV100950593; called by muse, mutect2, varscan2
- LPAR3 | c.654C>T p.N218= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs777206710, COSV101004667; called by muse, mutect2
- MCM4 | c.1308A>C p.A436= | Silent (SNP) | VAF 30/152 reads (20%) | catalogued as COSV100031207; called by muse, mutect2, varscan2
- MGP | c.129C>T p.F43= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99967074; called by muse, mutect2, varscan2
- MMP2 | c.1476C>T p.F492= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as rs1567380233, COSV99527387; called by muse, mutect2
- OR11H6 | c.846A>T p.S282= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV100209698; called by muse, mutect2
- OR4D1 | c.579C>T p.S193= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV99274017; called by muse, mutect2, varscan2
- PCDHA6 | c.15G>A p.P5= | Silent (SNP) | VAF 23/157 reads (15%) | catalogued as COSV100972077; called by muse, mutect2, varscan2
- PDE2A | c.1858C>T p.L620= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs969758682, COSV100557599; called by muse, mutect2
- PITPNM1 | c.2562C>T p.V854= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1388063768, COSV99653499; called by muse, mutect2
- PPIG | c.1149G>T p.G383= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99644122; called by muse, mutect2, varscan2
- PRKDC | c.4206G>T p.L1402= | Silent (SNP) | VAF 6/72 reads (8%) | catalogued as COSV100038264; called by muse, mutect2
- PRPH2 | c.553C>T p.L185= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as COSV100027935; called by muse, varscan2
- RPS27A | c.282G>A p.K94= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99702993; called by muse, mutect2, varscan2
- RYR2 | c.12084G>A p.S4028= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs751821960, COSV63682739, COSV63702754; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC23A2 | c.906A>T p.G302= | Silent (SNP) | VAF 8/166 reads (5%) | catalogued as COSV100594755; called by muse, mutect2
- SRSF11 | c.1227A>G p.E409= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs757016269, COSV100917794; called by muse, mutect2
- THUMPD3 | c.1383A>G p.V461= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs1183251591, COSV100560518; called by muse, mutect2, varscan2
- TRIM49 | c.1260G>T p.V420= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- UGT1A4 | c.72C>G p.P24= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV100529445; called by muse, mutect2, varscan2
- USP34 | c.2478T>C p.I826= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as rs747199302, COSV101276619; called by muse, mutect2, varscan2
- VWA8 | c.2949A>T p.I983= | Silent (SNP) | VAF 9/155 reads (6%) | catalogued as COSV99863532; called by muse, mutect2
- WNK1 | c.2617C>T p.L873= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs776249622, COSV60026785; called by muse, mutect2, varscan2
- ZNF69 | c.135G>A p.Q45= (on ENST00000429654 / NM_001364730.1; = p.Q31= on NM_021915.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/103 reads (12%) | catalogued as COSV100420871; called by muse, mutect2, varscan2
- ZNF749 | c.675G>A p.E225= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs560067836, COSV100494183; called by muse, mutect2
- DPP6 | c.627+21022A>G | Intron (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100122920; called by muse, varscan2
- KPNA4 | c.1032+267A>T | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as COSV100514967; called by muse, mutect2
- OR52A5 | c.-1C>A | 5'UTR (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100263285, COSV100263525; called by muse, mutect2, varscan2
